Gene-level copy-number profile of tumor specimen TARGET-40-PAPNVD-01A from TARGET case TARGET-40-PAPNVD, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 14.5 years (5,289 days).
Specimen TARGET-40-PAPNVD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.2d9d9eb7-9630-56b0-96b7-a8298ac1d1f8.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PAPNVD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 363 have no estimate.
https://portal.gdc.cancer.gov/files/d52a892c-6df4-4230-8bb0-c2805b2248a1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 350; copy number 1: 673; copy number 2: 11,223; copy number 3: 13,239; copy number 4: 11,239; copy number 5: 12,651; copy number 6: 8,040; copy number 7: 1,456; copy number 8: 891; copy number 9: 230; copy number 10: 12; copy number 11: 7; copy number 12: 7; copy number 13: 33; copy number 14: 5; copy number 15: 20; copy number 18: 47; copy number 19: 23; copy number 20: 6; copy number 22: 20; copy number 23: 82; copy number 27: 4; copy number 40: 2.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,614,098, 2 genes: LCE3C, LCE3B.
- chr13:48,488,963–49,209,779, 12 genes (within-gene range 0–4): RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2.
- chr15:34,489,002–34,495,900, 2 genes: HNRNPLP2, FSCN1P1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,845 genes in 37 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:155,845,367–157,949,071, 94 genes, copy number 7 (broad region; genes not listed).
- chr1:234,212,606–237,833,988, 91 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr1:242,882,066–248,919,946, 191 genes, copy number 8 (broad region; genes not listed).
- chr2:88,691,673–94,787,261, 130 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr3:189,238,686–189,240,594, 1 gene, copy number 9: TPRG1-AS2.
- chr4:147,344,629–147,344,717, 1 gene, copy number 7: MIR548G.
- chr5:58,198–15,266,541, 273 genes, copy number 8–10 (broad region; genes not listed).
- chr5:19,471,296–21,032,845, 8 genes, copy number 7 (within-gene range 3–7): CDH18, AC093303.1, AC094103.1, CDH18-AS1, LINC02146, LINC02241, AC138938.1, AC140168.1.
- chr5:23,951,348–29,882,945, 66 genes, copy number 8–14 (broad region; genes not listed).
- chr5:42,423,439–43,886,628, 45 genes, copy number 9: GHR, SERBP1P6, AC093225.1, AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.3, AC008875.2, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1.
- chr5:45,890,216–45,895,970, 1 gene, copy number 10: AC122694.1.
- chr7:66,995,173–67,239,519, 1 gene, copy number 15 (within-gene range 6–15): TYW1.
- chr7:67,114,322–68,319,676, 17 genes, copy number 15: MIR4650-1, SPDYE21, PMS2P4, Y_RNA, STAG3L4, AC006480.1, AC006480.2, MTATP6P21, MTCO3P41, AC005482.1, AC092648.1, AC092637.1, AC006013.1, MTCO1P57, AC093655.1, AC093655.2, MTND4P3.
- chr7:75,842,602–76,541,459, 29 genes, copy number 8: RHBDD2, POR, MIR4651, RPL7L1P3, SNORA14A, TMEM120A, STYXL1, AC006330.1, MDH2, AC005077.4, RNU6-863P, GTF2IP7, AC005077.2, AC005077.1, AC005077.3, SRRM3, HSPB1, YWHAG, PPIAP81, SSC4D, ZP3, DTX2, FDPSP2, AC005522.1, UPK3B, AC004980.4, Y_RNA, AC004980.3, SPDYE16.
- chr7:107,168,961–109,764,357, 38 genes, copy number 13–20: HBP1, AC004492.1, COG5, AC002381.1, GPR22, DUS4L, DUS4L-BCAP29, AC004839.2, BCAP29, AC004839.1, WBP1LP2, BANF1P5, SLC26A4-AS1, SLC26A4, AC002467.1, CBLL1, SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4, NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1, C7orf66, AC004014.2, AC004014.1, BUB3P1, AC002386.1, AC073071.1, AC073387.1, AC073387.2.
- chr8:92,144,088–105,804,539, 276 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr8:105,662,352–105,737,765, 3 genes, copy number 8: AC103853.1, AC103853.2, RPL12P24.
- chr8:111,376,639–113,616,958, 13 genes, copy number 9–13: LINC02237, SERPINA15P, H2AZP7, AC022360.1, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC055788.1, AC103993.1.
- chr8:114,791,653–129,844,504, 202 genes, copy number 7–27 (broad region; genes not listed).
- chr8:129,864,478–129,865,052, 1 gene, copy number 7: AC022973.2.
- chr13:48,389,567–48,444,704, 2 genes, copy number 8 (within-gene range 3–8): LPAR6, Metazoa_SRP.
- chr13:49,444,374–49,936,490, 13 genes, copy number 7: SETDB2, SNRPGP14, PHF11, RCBTB1, AL135901.1, ARL11, EBPL, KPNA3, AL136301.1, RNY4P30, CTAGE10P, RNY4P9, SPRYD7.
- chr13:49,995,888–50,020,481, 2 genes, copy number 7 (within-gene range 3–7): TRIM13, MIR3613.
- chr13:100,934,023–100,944,553, 1 gene, copy number 9: LINC00411.
- chr13:104,125,930–107,933,503, 35 genes, copy number 7: AL136524.1, RPL7P45, AL138954.1, DAOA-AS1, AL359751.2, AL359751.1, DAOA, AL359745.1, LINC00343, AL138701.1, AL138701.2, RNA5SP38, AL139379.1, LINC00460, RPL35P9, EFNB2, AL138689.2, AL138689.1, ARGLU1, LINC00551, LINC00443, ATP5MC1P5, AL163534.1, AL162574.2, PPIAP24, AL162574.1, AL162574.3, AL354741.1, FAM155A, SNORD31B, AL445649.1, MIR1267, FAM155A-IT1, AL359436.1, AL136964.1.
- chr14:23,469,689–25,156,314, 83 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr14:28,264,390–50,231,578, 320 genes, copy number 8 (broad region; genes not listed).
- chr14:51,637,348–51,651,744, 2 genes, copy number 7: AL122125.1, FRMD6-AS1.
- chr14:101,761,798–106,875,071, 340 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr18:30,713,275–32,745,567, 53 genes, copy number 8 (within-gene range 4–8): AC090506.1, AC090506.2, AC016382.1, RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7, AC025887.2, WBP11P1, AC009835.1, AC025887.1.
- chr18:36,273,574–37,565,827, 12 genes, copy number 7 (within-gene range 3–7): AC023043.2, AC023043.3, FHOD3, AC055840.1, TPGS2, KIAA1328, AC016493.1, AC015961.1, CELF4, AC015961.2, AC090386.1, AC090386.2.
- chr19:45,995,461–46,413,564, 26 genes, copy number 7: CCDC61, MIR769, PGLYRP1, AC007785.3, IGFL4, AC007785.1, AC007785.2, IGFL3, TGIF1P1, IGFL2, AC006262.2, IGFL2-AS1, IGFL1P1, AC006262.1, RPL12P41, AC006262.3, IGFL1, AC006262.4, IGFL1P2, HIF3A, RNU6-924P, AC007193.2, PPP5C, AC007193.1, AC007193.3, CCDC8.
- chr19:54,333,185–56,078,801, 127 genes, copy number 7 (broad region; genes not listed).
- chr20:1,561,385–1,620,061, 2 genes, copy number 40 (within-gene range 6–40): SIRPB1, AL049634.3.
- chr20:24,949,269–25,752,776, 32 genes, copy number 7: CST7, APMAP, RNU6-1257P, AL035661.2, ACSS1, AL080312.2, VSX1, AL080312.1, AL035252.2, AL035252.1, AL035252.5, ENTPD6, Y_RNA, AL035252.4, AL035252.3, AL121772.1, PYGB, AL121772.2, AL121772.3, ABHD12, PPIAP2, GINS1, NINL, RNU6ATAC17P, NANP, ZNF337-AS1, RN7SL594P, MED28P7, ZNF337, AL031673.1, AL390198.1, VN1R108P.
- chr21:12,999,676–17,894,485, 108 genes, copy number 7 (broad region; genes not listed).
- chr21:31,559,245–39,929,397, 206 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 487. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
